Somatic mutation profile of tumor specimen TCGA-B6-A0WW-01A (aliquot TCGA-B6-A0WW-01A-11D-A10G-09) from TCGA case TCGA-B6-A0WW, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage X; Age at diagnosis: 58.8 years (21,479 days).
Specimen TCGA-B6-A0WW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efb68702-7e0e-474d-a6b5-2855d963e3da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0WW-10A (Blood Derived Normal), aliquot TCGA-B6-A0WW-10A-01D-A10G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b66c8d20-4b92-40b5-8810-4502266d0a53

The open-access MAF lists 39 somatic variants for this specimen: 30 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 22, Silent 9, Frame Shift Del 3, Splice Region 2, Nonsense Mutation 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 68/204 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.796A>T p.K266* | Nonsense Mutation (SNP) | VAF 65/246 reads (26%) | catalogued as rs1554825260, COSV64289176; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASIC4 | c.686A>G p.D229G | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV100761600; called by muse, mutect2, varscan2
- BGN | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.315); catalogued as rs782454465, COSV59036049; called by muse, mutect2, varscan2
- C6orf118 | c.1091C>A p.A364E | Missense Mutation (SNP) | VAF 110/309 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0.014); catalogued as COSV57812972; called by muse, mutect2, varscan2
- CDKL1 | c.43T>A p.S15T | Missense Mutation (SNP) | VAF 106/264 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.117); catalogued as rs542432977, COSV53578189; called by muse, mutect2, varscan2
- COL27A1 | c.5220C>T p.V1740= | Splice Region (SNP) | VAF 16/164 reads (10%) | catalogued as rs886514953, COSV61925511; called by muse, varscan2
- CSAG1 | c.72G>C p.W24C | Missense Mutation (SNP) | VAF 257/676 reads (38%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.009); catalogued as rs1390725635, COSV63399914; called by muse, mutect2, varscan2
- CSMD3 | c.10997C>T p.S3666L (on ENST00000297405 / NM_001363185.1; = p.S3497L on NM_052900.3) | Missense Mutation (SNP) | VAF 278/1831 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52116331, COSV52133968; called by muse, mutect2, varscan2
- GOLGA8G | c.1177G>C p.E393Q | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV61550748; called by mutect2, varscan2
- GRAMD2A | c.697G>A p.V233M | Missense Mutation (SNP) | VAF 89/207 reads (43%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs544595021, COSV59032826; called by muse, mutect2, varscan2
- HCAR2 | c.121G>C p.G41R | Missense Mutation (SNP) | VAF 90/237 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1348029018, COSV61024435; called by muse, mutect2, varscan2
- HMG20A | c.450G>A p.Q150= | Splice Region (SNP) | VAF 40/113 reads (35%) | catalogued as COSV60311597; called by muse, mutect2, varscan2
- HSPA9 | c.1918C>G p.L640V | Missense Mutation (SNP) | VAF 171/498 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.106); catalogued as COSV51863507; called by muse, mutect2, varscan2
- KALRN | c.1066C>A p.H356N | Missense Mutation (SNP) | VAF 122/338 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV53755144; called by muse, mutect2, varscan2
- KCNN2 | c.396G>C p.K132N (on ENST00000264773; = p.K344N on NM_021614.4) | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53284202, COSV53292429; called by muse, mutect2, varscan2
- LHX5 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.783); catalogued as rs1182220666, COSV55662078; called by muse, mutect2, varscan2
- PEX7 | c.272C>G p.S91W | Missense Mutation (SNP) | VAF 75/222 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59248144; called by muse, mutect2, varscan2
- PIAS4 | c.1355C>T p.P452L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs764999661, COSV53678375, COSV99519081; called by muse, mutect2, varscan2
- PLA2G3 | c.1124T>C p.I375T | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1485788249, COSV53208097; called by muse, mutect2, varscan2
- PTEN | c.143del p.N48Tfs*6 | Frame Shift Del (DEL) | VAF 108/346 reads (31%) | catalogued as COSV64298680; called by mutect2, pindel, varscan2
- SLC9A8 | c.480T>G p.F160L | Missense Mutation (SNP) | VAF 213/564 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV64287343, COSV64288298; called by muse, mutect2, varscan2
- SLCO1B3 | c.728-1G>A p.X243_splice | Splice Site (SNP) | VAF 252/760 reads (33%) | catalogued as COSV53933585, COSV53945393; called by muse, mutect2, varscan2
- SPANXN2 | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 24/861 reads (3%) | SIFT tolerated (0.98); PolyPhen benign (0.005); catalogued as rs782516547, COSV100979825, COSV65127756; called by muse, mutect2
- UNCX | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100310303, COSV60332803, COSV60332865; called by muse, mutect2, varscan2
- UNCX | c.407A>C p.E136A | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60332877; called by muse, mutect2, varscan2
- USF3 | c.2731G>T p.D911Y | Missense Mutation (SNP) | VAF 143/392 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.947); catalogued as COSV57070368; called by muse, mutect2, varscan2
- ANKRD11 | c.67_77del p.E23Wfs*5 | Frame Shift Del (DEL) | VAF 16/181 reads (9%) | called by mutect2, pindel
- RIOK2 | c.900_903del p.S301Pfs*18 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | called by mutect2, pindel, varscan2
- SNRPB | c.-1_1dup p.M1? | Frame Shift Ins (INS) | VAF 21/74 reads (28%) | called by mutect2, pindel, varscan2
- BRSK2 | c.1239C>T p.I413= | Silent (SNP) | VAF 21/32 reads (66%) | catalogued as rs749513566, COSV100373085, COSV57540713; called by muse, mutect2, varscan2
- CIP2A | c.2181G>A p.L727= | Silent (SNP) | VAF 134/383 reads (35%) | catalogued as COSV55417445; called by muse, mutect2, varscan2
- HS3ST2 | c.849C>T p.G283= | Silent (SNP) | VAF 33/103 reads (32%) | catalogued as rs947875343, COSV54458927; called by muse, mutect2, varscan2
- LBR | c.900T>C p.Y300= | Silent (SNP) | VAF 27/105 reads (26%) | catalogued as rs1207710158, COSV55287750; called by muse, mutect2, varscan2
- MRC2 | c.3856C>T p.L1286= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as COSV57637330; called by muse, mutect2, varscan2
- OR5L2 | c.603G>T p.L201= | Silent (SNP) | VAF 185/514 reads (36%) | catalogued as COSV65723509; called by muse, mutect2, varscan2
- RTEL1 | c.2535G>C p.A845= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs751482700, COSV58891316; called by muse, mutect2, varscan2
- SMARCC1 | c.1554T>C p.D518= | Silent (SNP) | VAF 119/203 reads (59%) | catalogued as rs747800064, COSV54377858; called by muse, mutect2, varscan2
- SNRNP25 | c.177G>A p.Q59= (on ENST00000383018; = p.Q50= on NM_024571.4) | Silent (SNP) | VAF 78/224 reads (35%) | catalogued as COSV51953732, COSV51954351, COSV99244632; called by muse, mutect2, varscan2
